Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A5VC, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A5VC-01A (Primary Tumor).

ICD-0-3
Leiomyosarcoma NOS 8890/3
Site: ~~thigh~~ connective, subcutaneous
and other soft tissues of thigh
C49.2
~~soft~~ connective, subcutaneous and other
soft tissues of extremities
C49.9
JW 4/12/13

TSS DelD:
Surgery Date:

SPECIMENS:

- A. POSTERIOR RIGHT THIGH SARCOMA
- B. ADDITIONAL PROXIMAL MARGIN
- C. ADDITIONAL DISTAL MARGIN

DIAGNOSIS:

- A. SKIN AND SOFT TISSUE, POSTERIOR RIGHT THIGH, EXCISION:
- LEIOMYOSARCOMA (3.5 X 3.3 X 1.4 CM), INTERMEDIATE TO HIGH GRADE
- TUMOR IS 0.2 CM TO THE CLOSEST DEEP MARGIN
- SURGICAL MARGINS NEGATIVE FOR TUMOR
- B. SKIN AND SUBCUTANEOUS TISSUE, ADDITIONAL PROXIMAL MARGIN, EXCISION:
- NEGATIVE FOR TUMOR
- C. SKIN AND SUBCUTANEOUS TISSUE, ADDITIONAL DISTAL MARGIN, EXCISION:
- NEGATIVE FOR TUMOR

GROSS DESCRIPTION:

A. POSTERIOR RIGHT THIGH SARCOMA
Received fresh labeled with the patient's identification and "posterior right thigh sarcoma" is an oval shaped piece of tan skin, 10 x 8 cm excised to a depth of 2 cm with a suture designating the proximal position (specimen is also oriented by Dr.). There is a firm tan nodule, 3.2 x 3 cm located 2.5 cm from the medial and lateral margins, 4 cm from the proximal position, and 2.8 cm from the distal position. The posterior aspect is covered by fascia. Ink codes: Lateral-blue, medial-orange, posterior- black. On sectioning, there is a pink-tan fish-flesh nodule, 3.5 x 3.3 x 1.4 cm which is 1.1 cm from the distal margin and grossly does not appear to invade the fascia. A photograph is taken and tissue is procured; representatively submitted:

- A1: shave of proximal margin
- A2: cross section immediately proximal to nodule
- A3: shave of lateral margin adjacent to nodule
- A4: shave of medial margin adjacent to nodule
- A5-A7: nodule and relationship to deep margin/fascia
- A8-A10: nodule and relationship to skin
- A11: perpendicular section of lateral margin nearest nodule
- A12: perpendicular section of medial margin nearest nodule
- A13: cross section immediately distal to nodule
- A14: shave of distal margin

B. ADDITIONAL PROXIMAL MARGIN

Received in formalin labeled with the patient's identification and "additional proximal margin" is a triangular shaped piece of tan skin, 6 x 3 cm excised to a depth of 1 cm with a suture designating the proximal tip. The lateral margin is inked blue, medial margin-orange, and deep margin-green. Serial sectioning reveals no discrete lesions; representatively submitted:

- B1: proximal tip
- B2: shave of lateral and medial margins
- B3: cross section including deep margin

C. ADDITIONAL DISTAL MARGIN

Received in formalin labeled with the patient's identification and "additional distal margin" is a triangular shaped piece of tan skin, 3.4 x 1.4 cm excised to a depth of 1.5 cm with a suture designating the distal tip. Proximal portion has surgical staples. The lateral margin is inked blue, medial margin-orange, and deep margin-green. Specimen is serially sectioned revealing no discreet lesions; submitted entirely:

- C1: distal tip
- C2-C3: cross section submitted from distal to proximal

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Right posterior thigh sarcoma

IHPAA Discrepancy		

Source: NCI Genomic Data Commons file 8e296351-7e5e-4b3c-8132-6d48dd2867be (TCGA-QQ-A5VC.CAA2594C-8A1B-475C-8BBB-3220962F5104.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).